Gene-level copy-number profile of tumor specimen C3L-06206-04 from CPTAC case C3L-06206, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 71.8 years (26,220 days).
Specimen C3L-06206-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Head & Neck; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c25862c3-fa3a-4a7e-a9c7-d66cd943e2ce.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06206-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/41f64b2c-eac7-4b8c-9332-45b1868ae48c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 3,584; copy number 2: 48,334; copy number 3: 5,386; copy number 4: 28; copy number 5: 22; copy number 6: 868; copy number 7: 20; copy number 10: 151.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,341,826–7,385,558, 3 genes (within-gene range 0–1): AC130360.1, ZNF705G, DEFB108C.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,061 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–157,949,071, 644 genes, copy number 6–10 (broad region; genes not listed).
- chr1:160,796,074–167,591,846, 176 genes, copy number 6–10 (broad region; genes not listed).
- chr1:171,841,498–173,175,503, 21 genes, copy number 6: DNM3, DNM3-IT1, DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1, RNU6-157P, PIGC, C1orf105, SUCO, RNU6-693P, FASLG, SLC25A38P1, Z98043.1, AL031599.1, AIMP1P2, Z97198.1, TNFSF18, GOT2P2, AL022310.1.
- chr1:184,171,714–185,102,603, 16 genes, copy number 6: Y_RNA, Y_RNA, AL445228.1, RN7SL654P, AL445228.2, C1orf21, AL078645.1, AL078645.2, AL713852.1, EDEM3, NIBAN1, RNU7-13P, LINC01633, RNA5SP72, RNF2, FTH1P25.
- chr1:186,311,652–187,686,628, 15 genes, copy number 6 (within-gene range 2–6): TPR, RNU6-1240P, ODR4, PDC-AS1, PDC, AL096803.3, AL096803.1, AL096803.2, PTGS2, PACERR, PLA2G4A, LINC01036, AL391813.1, FDPSP1, AL357559.1.
- chr1:199,752,491–205,211,702, 167 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr5:44,388,732–44,828,592, 8 genes, copy number 5 (within-gene range 3–5): FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2.
- chr7:5,823,160–6,059,175, 11 genes, copy number 5 (within-gene range 3–5): ZNF815P, RN7SL556P, OCM, CCZ1, RSPH10B, PMS2, Y_RNA, AIMP2, SNORA80D, EIF2AK1, ANKRD61.
- chr7:83,363,238–83,649,139, 3 genes, copy number 5: SEMA3E, AC079799.2, AC079987.1.

Autosomal genes at a single copy (total copy number 1): 3,584. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
